Somatic mutation profile of tumor specimen TCGA-34-2604-01A (aliquot TCGA-34-2604-01A-01W-0877-08) from TCGA case TCGA-34-2604, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 81.7 years (29,827 days).
Specimen TCGA-34-2604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66b4a724-ac3c-446b-a766-9a09fba28d50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2604-11A (Solid Tissue Normal), aliquot TCGA-34-2604-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbfe8844-2c67-46b8-94de-677fae6d283b

The open-access MAF lists 656 somatic variants for this specimen: 501 protein-altering or splice-affecting, 138 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 431, Silent 138, Nonsense Mutation 26, Splice Site 22, Frame Shift Del 11, Intron 9, RNA 7, Splice Region 5, Frame Shift Ins 4, In Frame Ins 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 122/459 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ABCA10 | c.4337A>T p.Q1446L | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99289158; called by muse, mutect2, varscan2
- ABCA9 | c.2767+1G>T p.X923_splice | Splice Site (SNP) | VAF 388/1048 reads (37%) | catalogued as COSV100383370; called by muse, mutect2, varscan2
- ABCD2 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 64/291 reads (22%) | catalogued as COSV58052103; called by muse, mutect2, varscan2
- AC098582.1 | c.361A>T p.T121S | Missense Mutation (SNP) | VAF 80/911 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99985891; called by muse, mutect2
- ACSL3 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 41/388 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV100658057; called by muse, mutect2, varscan2
- ACTL9 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100185495; called by muse, mutect2, varscan2
- ACVRL1 | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 47/424 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV101188072; called by muse, mutect2, varscan2
- ADAM19 | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57422648; called by muse, mutect2, varscan2
- ADAM2 | c.875C>G p.A292G | Missense Mutation (SNP) | VAF 52/784 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs746985909, COSV99697743; called by muse, mutect2
- ADAM33 | c.1388G>A p.C463Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1378161696, COSV100598013; called by muse, mutect2, varscan2
- ADAM9 | c.2076T>G p.N692K | Missense Mutation (SNP) | VAF 135/1493 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV101166223; called by muse, mutect2
- ADARB1 | c.1807C>T p.R603W (on ENST00000360697 / NM_001346687.2; = p.R563W on NM_001112.4) | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100654052; called by muse, mutect2, varscan2
- ADCY8 | c.2783T>A p.L928H | Missense Mutation (SNP) | VAF 87/849 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99653670; called by muse, mutect2, varscan2
- ADGRA3 | c.2066C>A p.T689K | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99293679; called by muse, mutect2, varscan2
- ADGRV1 | c.11581G>T p.D3861Y | Missense Mutation (SNP) | VAF 283/1045 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1311978141, COSV101315645, COSV101316332; called by muse, mutect2, varscan2
- AK7 | c.1180C>G p.H394D | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99967473; called by muse, mutect2
- AK9 | c.5432C>A p.S1811Y | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV101413984; called by muse, mutect2, varscan2
- AKR7L | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV101334288, COSV101334372; called by muse, mutect2, varscan2
- ALB | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); catalogued as rs764279820, COSV55744073, COSV99892003, COSV99892412; called by muse, mutect2, varscan2
- ALOX15B | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV101205689; called by muse, mutect2, varscan2
- ALS2 | c.4864C>T p.H1622Y | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as COSV99969875; called by muse, mutect2, varscan2
- AMDHD2 | c.788T>C p.F263S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99566078; called by muse, mutect2, varscan2
- AMY2A | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 320/3526 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV70214824; called by muse, mutect2
- ANGPT4 | c.759C>G p.D253E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101124847; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2286T>G p.D762E | Missense Mutation (SNP) | VAF 66/439 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.05); catalogued as COSV99784108; called by muse, mutect2, varscan2
- ANKRD6 | c.46G>T p.V16L | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs536168606, COSV100329629, COSV60229553, COSV60237701; called by muse, mutect2
- ANKS1B | c.1740G>C p.E580D | Missense Mutation (SNP) | VAF 58/378 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1397783827, COSV100247276; called by muse, mutect2, varscan2
- ANO10 | c.593-2A>G p.X198_splice | Splice Site (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99428857; called by muse, mutect2, varscan2
- ANO3 | c.2729T>G p.L910R | Missense Mutation (SNP) | VAF 184/615 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99884865; called by muse, mutect2, varscan2
- ANXA3 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 304/2024 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99363890; called by muse, varscan2
- APBA1 | c.1805A>T p.Q602L | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99596881; called by muse, mutect2, varscan2
- ARHGEF19 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV99580690; called by muse, mutect2, varscan2
- ARMH4 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV99958759; called by muse, mutect2
- ASB11 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 57/381 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs1031381638, COSV100729112; called by muse, mutect2, varscan2
- ASB5 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 87/589 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV99641996; called by muse, mutect2, varscan2
- ASIC5 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs745353708, COSV101611163, COSV73332867; called by muse, mutect2, varscan2
- ASPRV1 | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 333/1420 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100208601; called by muse, mutect2, varscan2
- ASTN1 | c.3545A>T p.D1182V | Missense Mutation (SNP) | VAF 70/991 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100707577; called by muse, mutect2
- ATP10A | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100791431; called by muse, mutect2, varscan2
- ATP11A | c.2926G>C p.A976P | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99369648; called by muse, mutect2, varscan2
- ATP6V1E1 | c.277-1G>T p.X93_splice | Splice Site (SNP) | VAF 238/1158 reads (21%) | catalogued as COSV99494417; called by muse, mutect2, varscan2
- ATP8A1 | c.3025A>G p.I1009V | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100047033; called by muse, mutect2, varscan2
- ATRNL1 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 98/481 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV100746724; called by muse, mutect2, varscan2
- BFSP2 | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV100183873; called by muse, mutect2, varscan2
- BTBD7 | c.2221G>C p.A741P | Missense Mutation (SNP) | VAF 82/735 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV100598102; called by muse, mutect2, varscan2
- C14orf28 | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100290331; called by muse, mutect2, varscan2
- C3AR1 | c.955A>C p.N319H | Missense Mutation (SNP) | VAF 332/1081 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV99368845; called by muse, mutect2, varscan2
- C4BPA | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.093); catalogued as rs779478751, COSV100891272; called by muse, mutect2, varscan2
- C6 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 112/664 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99667590; called by muse, mutect2, varscan2
- C6orf118 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.013); catalogued as COSV100024879, COSV100024951, COSV57813264; called by muse, mutect2, varscan2
- C8B | c.1652G>A p.W551* | Nonsense Mutation (SNP) | VAF 44/603 reads (7%) | catalogued as COSV100980862; called by muse, mutect2
- CACNA1B | c.627G>T p.L209F | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99499029; called by muse, mutect2, varscan2
- CACNA1G | c.4422G>A p.Q1474= | Splice Region (SNP) | VAF 59/144 reads (41%) | catalogued as COSV100662338; called by muse, mutect2, varscan2
- CACNG7 | c.706G>C p.A236P | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99712225; called by muse, mutect2, varscan2
- CBLL2 | c.578T>A p.V193E | Missense Mutation (SNP) | VAF 108/807 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as COSV100081700; called by muse, mutect2, varscan2
- CCDC58 | c.51G>A p.Q17= | Splice Region (SNP) | VAF 207/434 reads (48%) | catalogued as COSV99216443; called by muse, mutect2, varscan2
- CCDC88C | c.1514A>T p.Q505L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV101106032; called by muse, mutect2, varscan2
- CCN2 | c.949A>G p.M317V | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.994); catalogued as rs752118942, COSV100915318, COSV100915349; called by muse, mutect2
- CCR8 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413152; called by muse, mutect2, varscan2
- CD163L1 | c.2373C>A p.A791= | Splice Region (SNP) | VAF 67/261 reads (26%) | catalogued as COSV100550539; called by muse, mutect2, varscan2
- CD1A | c.972C>A p.R324= | Splice Region (SNP) | VAF 227/1645 reads (14%) | catalogued as COSV99192555; called by muse, mutect2, varscan2
- CD36 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 97/376 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV59209648, COSV99987784; called by muse, mutect2, varscan2
- CDC73 | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100813948; called by muse, mutect2
- CDCA7 | c.470G>T p.R157M (on ENST00000347703 / NM_145810.3; = p.R236M on NM_031942.5) | Missense Mutation (SNP) | VAF 39/400 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100143708; called by muse, mutect2
- CDH19 | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV100050631, COSV100052056; called by muse, mutect2, varscan2
- CENPE | c.7180A>G p.K2394E | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99478800; called by muse, mutect2, varscan2
- CEP170 | c.4220G>T p.S1407I | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100317632; called by muse, mutect2, varscan2
- CEP43 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV100835713, COSV62761283; called by muse, mutect2, varscan2
- CFAP36 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100171111; called by mutect2, varscan2
- CFAP47 | c.1835C>A p.P612Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV99935641; called by muse, mutect2, varscan2
- CFAP47 | c.5255T>C p.L1752S | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100545623; called by muse, mutect2, varscan2
- CFAP61 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 236/1414 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs371793125, COSV55639118; called by muse, varscan2
- CFAP61 | c.3059C>A p.P1020H | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99846165; called by muse, mutect2, varscan2
- CFHR2 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 42/583 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV100804377; called by muse, mutect2
- CGNL1 | c.517A>G p.N173D | Missense Mutation (SNP) | VAF 99/456 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99848919; called by muse, mutect2, varscan2
- CHD6 | c.3287A>C p.E1096A | Missense Mutation (SNP) | VAF 95/582 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100498571; called by muse, mutect2, varscan2
- CHL1 | c.2138G>C p.R713T (on ENST00000397491 / NM_001253387.1; = p.R729T on NM_006614.4) | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs757916934, COSV99852005; called by muse, varscan2
- CHMP7 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV100500715; called by mutect2, varscan2
- CHPF | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99705212; called by muse, mutect2, varscan2
- CHRNA1 | c.826C>A p.L276M (on ENST00000261007 / NM_001039523.3; = p.L251M on NM_000079.4) | Missense Mutation (SNP) | VAF 54/575 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99650634; called by muse, mutect2
- CMYA5 | c.6820G>T p.D2274Y | Missense Mutation (SNP) | VAF 106/435 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as COSV71404665; called by muse, mutect2, varscan2
- CNTRL | c.2947G>T p.V983L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.919); catalogued as COSV53047316, COSV99443367; called by muse, mutect2, varscan2
- COBLL1 | c.883G>T p.A295S (on ENST00000392717; = p.A257S on NM_014900.5) | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52063980; called by muse, mutect2, varscan2
- COL11A2 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100554398; called by muse, mutect2, varscan2
- COL12A1 | c.4028T>G p.L1343* | Nonsense Mutation (SNP) | VAF 67/541 reads (12%) | catalogued as COSV100486346; called by muse, mutect2, varscan2
- COL19A1 | c.2677G>T p.G893C | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100507137; called by muse, mutect2, varscan2
- COL4A1 | c.4832C>T p.A1611V | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs775233741, COSV65423218, COSV65434312; called by mutect2, varscan2
- COL4A4 | c.1297G>T p.G433* | Nonsense Mutation (SNP) | VAF 60/266 reads (23%) | catalogued as COSV100307462, COSV61629784; called by muse, mutect2, varscan2
- CORO7 | c.849G>T p.R283S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99228021; called by muse, mutect2, varscan2
- CR1 | c.4148C>T p.P1383L | Missense Mutation (SNP) | VAF 301/1255 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100887960; called by muse, mutect2, varscan2
- CRAT | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100534167; called by muse, mutect2, varscan2
- CREBRF | c.377C>G p.P126R | Missense Mutation (SNP) | VAF 40/616 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99756245; called by muse, mutect2
- CRYBG3 | c.6529G>C p.D2177H | Missense Mutation (SNP) | VAF 129/450 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51709468, COSV99477338; called by muse, mutect2, varscan2
- CSMD3 | c.6115G>T p.G2039* (on ENST00000297405 / NM_001363185.1; = p.G1935* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 111/526 reads (21%) | catalogued as COSV99828407; called by muse, mutect2, varscan2
- CUL2 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101039256; called by muse, mutect2, varscan2
- CWH43 | c.1866-1G>C p.X622_splice | Splice Site (SNP) | VAF 71/824 reads (9%) | catalogued as COSV99893830; called by muse, mutect2
- CYLD | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 100/443 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100282676; called by muse, mutect2, varscan2
- CYP8B1 | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100296249; called by muse, mutect2, varscan2
- DACT3 | c.1808T>G p.V603G | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100340470; called by muse, varscan2
- DDX20 | c.2377C>A p.H793N | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100862328; called by muse, mutect2
- DDX54 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.277); catalogued as COSV58371928; called by mutect2, varscan2
- DEPDC5 | c.3521C>T p.P1174L (on ENST00000400246; = p.P1243L on NM_014662.5) | Missense Mutation (SNP) | VAF 44/367 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99834147; called by muse, mutect2, varscan2
- DEUP1 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV99977485; called by muse, mutect2, varscan2
- DGKB | c.2362A>G p.T788A | Missense Mutation (SNP) | VAF 61/562 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99342353; called by muse, mutect2, varscan2
- DNAH11 | c.5589C>A p.S1863R | Missense Mutation (SNP) | VAF 117/582 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV100180263; called by muse, mutect2, varscan2
- DNAH5 | c.12771C>A p.D4257E | Missense Mutation (SNP) | VAF 90/382 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200349959, COSV54233919; called by muse, mutect2, varscan2
- DNAH7 | c.7632A>T p.L2544F | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267599138, COSV100416861; called by muse, mutect2, varscan2
- DNAH7 | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 168/877 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as rs777242244, COSV100416862; called by muse, mutect2, varscan2
- DNAH8 | c.11025C>G p.N3675K | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100546729; called by muse, mutect2
- DNAH9 | c.5788G>T p.E1930* | Nonsense Mutation (SNP) | VAF 30/191 reads (16%) | catalogued as COSV99307421; called by muse, mutect2, varscan2
- DNAI3 | c.2465A>T p.E822V | Missense Mutation (SNP) | VAF 172/643 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV99642276; called by muse, mutect2, varscan2
- DNAJC13 | c.620G>C p.R207P | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.071); catalogued as COSV99607853; called by muse, mutect2, varscan2
- DRD3 | c.1006+1G>A p.X336_splice | Splice Site (SNP) | VAF 21/144 reads (15%) | catalogued as COSV99879625; called by muse, mutect2, varscan2
- DRGX | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV100938379; called by muse, mutect2, varscan2
- DYM | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 60/448 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.802); catalogued as COSV99493849; called by muse, mutect2, varscan2
- DYSF | c.5857C>T p.P1953S | Missense Mutation (SNP) | VAF 108/503 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as rs751990869, COSV99249772; called by muse, mutect2, varscan2
- DZIP3 | c.2249G>T p.R750M | Missense Mutation (SNP) | VAF 99/763 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100847984; called by muse, mutect2, varscan2
- EIF2B1 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57459760, COSV99967639; called by muse, mutect2, varscan2
- EPHX2 | c.185A>T p.Q62L | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV100994742; called by muse, mutect2, varscan2
- EPS15L1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1380654722, COSV99933215, COSV99933532; called by muse, mutect2, varscan2
- ESRRG | c.590-1G>A p.X197_splice | Splice Site (SNP) | VAF 26/203 reads (13%) | catalogued as COSV63148166; called by muse, mutect2, varscan2
- F8 | c.6325C>A p.R2109S | Missense Mutation (SNP) | VAF 304/894 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.4); catalogued as CM001998, COSV100811770, COSV100811958; called by muse, mutect2, varscan2
- FAM170A | c.825C>A p.S275R | Missense Mutation (SNP) | VAF 211/848 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.238); catalogued as COSV100089243; called by muse, varscan2
- FANCM | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | catalogued as COSV99361110; called by muse, mutect2
- FAT1 | c.10855G>T p.G3619W | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499574; called by muse, mutect2, varscan2
- FFAR1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs772248176, COSV99323641; called by mutect2, varscan2
- FGD3 | c.610A>T p.I204F | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100490790; called by muse, mutect2, varscan2
- FGF10 | c.326G>T p.S109I | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99240888; called by muse, mutect2, varscan2
- FMN2 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV100146758; called by mutect2, varscan2
- FPR3 | c.633C>G p.S211R | Missense Mutation (SNP) | VAF 147/821 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV100200839, COSV59331090; called by muse, mutect2, varscan2
- FSTL5 | c.2281A>T p.S761C | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV100059617; called by muse, mutect2, varscan2
- FUT5 | c.121G>C p.A41P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99398932; called by mutect2, varscan2
- GAB4 | c.471A>C p.E157D | Missense Mutation (SNP) | VAF 428/1447 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV101272076; called by muse, mutect2, varscan2
- GABRB2 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 76/731 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99196429; called by muse, mutect2, varscan2
- GALNT17 | c.973A>C p.M325L | Missense Mutation (SNP) | VAF 91/459 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as COSV100355480; called by muse, mutect2, varscan2
- GBA3 | c.607A>G p.R203G | Missense Mutation (SNP) | VAF 129/619 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs1427487267, COSV101545546; called by muse, mutect2, varscan2
- GLMN | c.791G>T p.R264M | Missense Mutation (SNP) | VAF 71/440 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as COSV100950149; called by muse, mutect2, varscan2
- GLMP | c.509G>C p.S170T | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.541); catalogued as COSV99828054; called by muse, mutect2, varscan2
- GLRX5 | c.333A>T p.Q111H | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495926; called by muse, mutect2, varscan2
- GORAB | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 66/615 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100883859; called by muse, mutect2, varscan2
- GOT1L1 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294654; called by muse, mutect2
- GPR149 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV101078658, COSV67670597; called by muse, mutect2, varscan2
- GPR158 | c.2845G>T p.D949Y | Missense Mutation (SNP) | VAF 85/462 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs138563761, COSV66265206; called by muse, mutect2, varscan2
- GPR50 | c.1758C>G p.D586E | Missense Mutation (SNP) | VAF 61/814 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99506469; called by muse, mutect2
- GPRC6A | c.2158A>T p.T720S | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as COSV100114634; called by muse, mutect2, varscan2
- GPX5 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 205/1292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101297280; called by muse, mutect2, varscan2
- GRM1 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 60/453 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV99268314; called by muse, mutect2, varscan2
- GRM4 | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs371727193; called by muse, mutect2, varscan2
- GRM7 | c.1986G>T p.L662F | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100737925; called by muse, mutect2, varscan2
- GSK3B | c.992C>T p.P331L (on ENST00000264235 / NM_001146156.2; = p.P344L on NM_002093.4) | Missense Mutation (SNP) | VAF 89/518 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99955368; called by muse, mutect2, varscan2
- GSK3B | c.937G>C p.A313P (on ENST00000264235 / NM_001146156.2; = p.A326P on NM_002093.4) | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99955371; called by muse, mutect2, varscan2
- GUCY1A1 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.926); catalogued as COSV99638347, COSV99639023; called by muse, mutect2, varscan2
- HEATR5B | c.3301G>T p.V1101L | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99250031; called by muse, mutect2
- HMCN1 | c.14126G>T p.W4709L | Missense Mutation (SNP) | VAF 197/1187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99633989; called by muse, mutect2, varscan2
- HPS6 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100154953; called by muse, mutect2, varscan2
- HTATIP2 | c.138A>T p.K46N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV101346180; called by muse, mutect2
- IFI44L | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 76/617 reads (12%) | catalogued as COSV100655065; called by muse, mutect2, varscan2
- IGDCC3 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100031432; called by muse, mutect2, varscan2
- IGHV1-46 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 98/670 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs782115511; called by muse, varscan2
- IGHV3-72 | c.163T>A p.W55R | Missense Mutation (SNP) | VAF 55/483 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV101455375; called by muse, mutect2, varscan2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 15/138 reads (11%) | catalogued as rs745545309; called by mutect2, varscan2
- IMP4 | c.270_271insT p.R91Sfs*30 | Frame Shift Ins (INS) | VAF 12/77 reads (16%) | catalogued as COSV99383824; called by mutect2, pindel, varscan2
- IQCC | c.254A>T p.N85I | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV99356762; called by muse, mutect2
- IRF6 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 37/358 reads (10%) | catalogued as COSV100884020; called by muse, mutect2, varscan2
- ITGA2B | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.284); catalogued as COSV99289156; called by muse, mutect2, varscan2
- ITPRID1 | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100087218, COSV60072072; called by muse, mutect2, varscan2
- JMJD1C | c.4881A>T p.E1627D | Missense Mutation (SNP) | VAF 90/290 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100550758; called by muse, mutect2, varscan2
- JUN | c.44A>T p.N15I | Missense Mutation (SNP) | VAF 55/361 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.522); catalogued as COSV100973474; called by muse, mutect2, varscan2
- KCNH5 | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 90/824 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100526701; called by muse, mutect2, varscan2
- KCNJ1 | c.49A>T p.T17S | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100131447; called by muse, mutect2, varscan2
- KCNK10 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 66/541 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV100069045, COSV56646944; called by muse, mutect2, varscan2
- KCNK3 | c.738C>A p.F246L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV100257084; called by mutect2, varscan2
- KCNK9 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271511; called by muse, mutect2, varscan2
- KCNQ3 | c.689G>C p.R230P | Missense Mutation (SNP) | VAF 78/784 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101196319, COSV66465699; called by muse, mutect2
- KDM3A | c.1823A>C p.K608T | Missense Mutation (SNP) | VAF 270/962 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV100460830, COSV57225080; called by mutect2, varscan2
- KERA | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 155/644 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.102); catalogued as rs1387243299, COSV99899526; called by muse, mutect2, varscan2
- KIAA1549 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 122/1285 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99651668; called by muse, mutect2, varscan2
- KIF2B | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 48/393 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV52132386, COSV52136561; called by muse, mutect2, varscan2
- KLHL4 | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV64139230; called by muse, mutect2, varscan2
- KMO | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 155/802 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844714; called by muse, mutect2, varscan2
- KPNA3 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 96/432 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99904323; called by muse, varscan2
- KRT6C | c.1218G>C p.Q406H | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99360149; called by muse, mutect2
- KRTAP10-9 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV100554998; called by muse, mutect2, varscan2
- KRTAP11-1 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60095258; called by muse, mutect2, varscan2
- KYNU | c.955+1G>T p.X319_splice | Splice Site (SNP) | VAF 39/171 reads (23%) | catalogued as COSV99933796; called by muse, mutect2, varscan2
- LAMA2 | c.2322G>T p.L774= | Splice Region (SNP) | VAF 188/1183 reads (16%) | catalogued as COSV101370744; called by muse, mutect2, varscan2
- LARS1 | c.2671G>T p.V891F (on ENST00000394434 / NM_020117.11; = p.V864F on NM_016460.3) | Missense Mutation (SNP) | VAF 66/325 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs754663860, COSV50976312, COSV99198733; called by muse, mutect2, varscan2
- LCOR | c.3775G>T p.A1259S | Missense Mutation (SNP) | VAF 114/617 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as COSV99617091; called by muse, mutect2, varscan2
- LILRB5 | c.655+1G>T p.X219_splice | Splice Site (SNP) | VAF 30/96 reads (31%) | catalogued as rs1569062130, COSV100300690; called by muse, mutect2, varscan2
- LINGO1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1200453719, COSV62436222; called by muse, mutect2, varscan2
- LINGO4 | c.1434C>A p.D478E | Missense Mutation (SNP) | VAF 82/482 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100765023; called by muse, varscan2
- LNX1 | c.928G>T p.G310W (on ENST00000263925 / NM_001126328.3; = p.G214W on NM_032622.2) | Missense Mutation (SNP) | VAF 58/562 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99820385; called by muse, mutect2
- LPIN3 | c.1942A>T p.T648S | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100182764; called by muse, mutect2, varscan2
- LRFN5 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985010; called by muse, mutect2
- LRFN5 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV53261940, COSV99985012; called by muse, mutect2, varscan2
- LRP10 | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100612461; called by mutect2, varscan2
- LRP1B | c.6955C>A p.H2319N | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101259476, COSV67223213; called by muse, mutect2, varscan2
- LRP1B | c.1544C>A p.S515* | Nonsense Mutation (SNP) | VAF 61/259 reads (24%) | catalogued as rs1558829171, COSV67200346; called by muse, mutect2, varscan2
- LRRC30 | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV101274443; called by muse, mutect2, varscan2
- LRRC40 | c.1065+1G>T p.X355_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100918834; called by muse, mutect2, varscan2
- LRRC66 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 173/744 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100603052; called by muse, mutect2, varscan2
- LRRC7 | c.1312G>A p.D438N (on ENST00000651989 / NM_001370785.2; = p.D405N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99228928, COSV99230791; called by muse, mutect2, varscan2
- LTBP3 | c.2431T>C p.C811R | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99534465; called by muse, mutect2, varscan2
- LYPD6B | c.107G>C p.W36S (on ENST00000409029 / NM_001317004.1; = p.W60S on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 235/1332 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV99700429; called by muse, mutect2, varscan2
- MAGEC3 | c.749A>C p.Y250S | Missense Mutation (SNP) | VAF 112/547 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100025923, COSV53580124; called by muse, mutect2, varscan2
- MAP2 | c.4906A>T p.I1636F | Missense Mutation (SNP) | VAF 114/409 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV52288139, COSV99561327; called by muse, mutect2, varscan2
- MAP3K19 | c.3411C>A p.S1137R | Missense Mutation (SNP) | VAF 78/478 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100209063, COSV59641438; called by muse, mutect2, varscan2
- MAP3K19 | c.2414C>A p.S805* | Nonsense Mutation (SNP) | VAF 29/177 reads (16%) | catalogued as COSV100209064, COSV100209511, COSV59638494; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV53798101, COSV99571685; called by muse, mutect2, varscan2
- MARCO | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 119/541 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.32); catalogued as rs1400383392, COSV59055668; called by muse, mutect2, varscan2
- MBD6 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV63076388; called by muse, mutect2
- MBOAT2 | c.1358A>C p.H453P | Missense Mutation (SNP) | VAF 36/441 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100020519; called by muse, mutect2
- MBOAT2 | c.1357C>A p.H453N | Missense Mutation (SNP) | VAF 36/437 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226877825, COSV100020521; called by muse, mutect2
- MCM4 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100031787; called by muse, mutect2, varscan2
- MEPE | c.1328T>A p.L443H | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV100734981; called by muse, mutect2
- MERTK | c.2726G>T p.R909L | Missense Mutation (SNP) | VAF 107/756 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as CM066130, COSV99775118; called by muse, mutect2, varscan2
- MME | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 615/1400 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1005427481, COSV100852497; called by muse, varscan2
- MME | c.358+2T>C p.X120_splice | Splice Site (SNP) | VAF 412/910 reads (45%) | catalogued as COSV100852498; called by muse, varscan2
- MPEG1 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV99915861; called by muse, mutect2, varscan2
- MRPL58 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.215); catalogued as COSV100043037; called by muse, mutect2, varscan2
- MS4A14 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 126/451 reads (28%) | catalogued as COSV100280664; called by muse, mutect2, varscan2
- MSH4 | c.2293A>T p.T765S | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99592287; called by muse, mutect2, varscan2
- MTOR | c.6088G>A p.G2030S | Missense Mutation (SNP) | VAF 74/698 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV100816565; called by muse, mutect2
- MUC16 | c.23736A>T p.L7912F | Missense Mutation (SNP) | VAF 299/1208 reads (25%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.12); catalogued as COSV101200849; called by muse, mutect2, varscan2
- MUC16 | c.13673G>A p.S4558N | Missense Mutation (SNP) | VAF 148/618 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV101200850; called by muse, mutect2, varscan2
- MUC17 | c.4895T>C p.L1632P | Missense Mutation (SNP) | VAF 206/815 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768593476, COSV100074637; called by muse, mutect2, varscan2
- MUC4 | c.16136G>T p.G5379V (on ENST00000463781 / NM_018406.7; = p.G1143V on NM_004532.6) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100206001; called by muse, mutect2, varscan2
- MYBPC3 | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765356720, COSV99920857; called by muse, mutect2, varscan2
- MYH14 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV99223694; called by muse, mutect2, varscan2
- MYH4 | c.3919C>G p.R1307G | Missense Mutation (SNP) | VAF 70/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99701952; called by muse, mutect2, varscan2
- MYH8 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 55/338 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200421774, COSV67973440; called by muse, mutect2, varscan2
- MYL1 | c.18C>G p.D6E | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100751687, COSV100751700; called by muse, mutect2, varscan2
- MYO7B | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748812090, COSV67347950; called by mutect2, varscan2
- NAA11 | c.30C>A p.D10E | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99727539; called by muse, mutect2, varscan2
- NAALADL2 | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 121/879 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs1234584920, COSV101380418, COSV69155431; called by muse, mutect2, varscan2
- NAV3 | c.4442-2A>T p.X1481_splice | Splice Site (SNP) | VAF 13/93 reads (14%) | catalogued as rs753494158, COSV99894278; called by muse, mutect2
- NCAM2 | c.338-1G>C p.X113_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99524666, COSV99525897; called by muse, mutect2, varscan2
- NCAN | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV99388035; called by muse, mutect2, varscan2
- NCR1 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 75/505 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52557489; called by muse, mutect2, varscan2
- NEBL | c.2333A>G p.N778S | Missense Mutation (SNP) | VAF 73/633 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV101009309; called by muse, mutect2, varscan2
- NHS | c.2819G>T p.R940I | Missense Mutation (SNP) | VAF 149/897 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101196893; called by muse, mutect2, varscan2
- NISCH | c.665_666insCTC p.V222_E223insS | In Frame Ins (INS) | VAF 10/96 reads (10%) | catalogued as COSV100617603; called by mutect2, pindel
- NLN | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV101114428; called by muse, mutect2, varscan2
- NLRP5 | c.2583A>T p.L861F | Missense Mutation (SNP) | VAF 250/1165 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101173833; called by muse, mutect2, varscan2
- NOTCH4 | c.3039G>T p.Q1013H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV100900904; called by muse, mutect2, varscan2
- NPC1 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99341774; called by muse, mutect2
- NPHS1 | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62286552; called by muse, mutect2, varscan2
- NPHS1 | c.2260G>T p.G754W | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546810048, COSV100800181; called by muse, mutect2, varscan2
- NPNT | c.1653A>T p.L551F | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99975369; called by muse, mutect2, varscan2
- NR3C2 | c.797G>T p.S266I | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100679622; called by muse, mutect2, varscan2
- NRCAM | c.2639G>A p.G880D (on ENST00000379028 / NM_001371124.1; = p.G864D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100695249; called by muse, mutect2, varscan2
- OLFML2A | c.1898G>A p.R633Q | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs377560457; called by muse, mutect2, varscan2
- OPN5 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 190/651 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99789986; called by muse, mutect2, varscan2
- OR10A7 | c.469A>G p.M157V | Missense Mutation (SNP) | VAF 49/567 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs934340032, COSV58277807; called by muse, mutect2
- OR14C36 | c.116del p.G39Efs*6 | Frame Shift Del (DEL) | VAF 122/1118 reads (11%) | catalogued as COSV58602136, COSV58603027; called by mutect2, pindel, varscan2
- OR1A1 | c.911A>T p.N304I | Missense Mutation (SNP) | VAF 127/651 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100410811; called by muse, mutect2, varscan2
- OR1B1 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100506520, COSV59171265; called by muse, mutect2, varscan2
- OR2D2 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 296/1088 reads (27%) | catalogued as rs775862453, COSV100203904; called by muse, mutect2, varscan2
- OR2F1 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 232/1601 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231325; called by muse, mutect2, varscan2
- OR2L2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 328/1621 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142994715, COSV63549338; called by muse, mutect2, varscan2
- OR2L2 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 334/1553 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.162); catalogued as COSV100824253; called by muse, mutect2, varscan2
- OR2T34 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100170487; called by muse, mutect2, varscan2
- OR2W3 | c.120del p.G41Afs*94 | Frame Shift Del (DEL) | VAF 106/784 reads (14%) | catalogued as COSV100831654, COSV100831783; called by mutect2, pindel*, varscan2
- OR4D6 | c.168C>G p.H56Q | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as COSV100271796; called by muse, mutect2, varscan2
- OR4Q3 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 128/1178 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100057209, COSV100057282; called by muse, mutect2, varscan2
- OR51A7 | c.198G>T p.L66F | Missense Mutation (SNP) | VAF 190/595 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049660650, COSV100834730; called by muse, mutect2, varscan2
- OR51I2 | c.185T>A p.F62Y | Missense Mutation (SNP) | VAF 146/441 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100413449; called by muse, mutect2, varscan2
- OR52E8 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 148/488 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs551753112, COSV101190402, COSV66207529; called by muse, mutect2, varscan2
- OR5P3 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as COSV100103243; called by muse, mutect2, varscan2
- OR6C3 | c.726G>C p.M242I | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); catalogued as rs745974102, COSV101110378; called by muse, varscan2
- OR6C74 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 83/637 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV59606924, COSV59607419; called by muse, mutect2, varscan2
- OR6F1 | c.567C>A p.C189* | Nonsense Mutation (SNP) | VAF 110/858 reads (13%) | catalogued as COSV100129392; called by muse, mutect2, varscan2
- OR8G1 | c.37A>C p.I13L | Missense Mutation (SNP) | VAF 140/414 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV100422581; called by muse, mutect2, varscan2
- OR9A2 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100628279; called by muse, mutect2, varscan2
- OR9Q2 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 192/586 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.769); catalogued as COSV100285501; called by muse, mutect2, varscan2
- PADI1 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 89/509 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs774174409, COSV100968559; called by muse, mutect2, varscan2
- PALB2 | c.3201+1G>A p.X1067_splice | Splice Site (SNP) | VAF 21/115 reads (18%) | catalogued as CS122634, COSV99848864; called by muse, mutect2, varscan2
- PAQR6 | c.524T>G p.L175R (on ENST00000292291 / NM_001272108.2; = p.L69R on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV99431525; called by muse, mutect2, varscan2
- PASD1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 58/510 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100949531, COSV100949696; called by muse, varscan2
- PCDH11X | c.3006G>T p.E1002D | Missense Mutation (SNP) | VAF 69/440 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100014184; called by muse, mutect2, varscan2
- PCDH15 | c.4928C>A p.S1643Y | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT deleterious, low confidence (0); catalogued as COSV100905375; called by muse, varscan2
- PCDH18 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100787456; called by muse, mutect2
- PCDHA7 | c.286T>A p.C96S | Missense Mutation (SNP) | VAF 27/476 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100971709; called by muse, mutect2
- PCDHB1 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV100128336; called by muse, mutect2, varscan2
- PCLO | c.5662A>G p.T1888A | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100436267; called by muse, mutect2, varscan2
- PCNX3 | c.5204G>A p.R1735H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs775172031, COSV63136601; called by muse, mutect2, varscan2
- PCNX4 | c.3014G>C p.W1005S (on ENST00000406854 / NM_001330177.2; = p.W771S on NM_022495.5) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100470692, COSV58302317; called by mutect2, varscan2
- PCSK6 | c.983A>G p.Y328C | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as rs1031984432, COSV100083939; called by muse, mutect2
- PDCL | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 123/723 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV52342381, COSV99414207; called by muse, mutect2, varscan2
- PEG3 | c.3386A>G p.H1129R | Missense Mutation (SNP) | VAF 166/968 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV99690015; called by muse, mutect2, varscan2
- PEX5L | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 502/1203 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as COSV55849678; called by muse, mutect2, varscan2
- PKD2 | c.2542C>T p.R848W | Missense Mutation (SNP) | VAF 56/756 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99418015; called by muse, mutect2
- PKHD1L1 | c.2595G>T p.Q865H | Missense Mutation (SNP) | VAF 46/414 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101006662; called by muse, mutect2, varscan2
- PKHD1L1 | c.2728G>T p.V910F | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101006663; called by muse, mutect2, varscan2
- PLAGL2 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99867475; called by muse, mutect2, varscan2
- PLXND1 | c.5323A>C p.I1775L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100140271; called by muse, mutect2, varscan2
- PM20D1 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs142439282, COSV65649184; called by muse, mutect2, varscan2
- PNLIP | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); catalogued as COSV100981933; called by muse, mutect2, varscan2
- POM121L12 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as COSV101374960, COSV68693781; called by muse, mutect2, varscan2
- POSTN | c.1163T>A p.V388E | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV101123453; called by muse, mutect2, varscan2
- PPM1K | c.59G>T p.R20I | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV99901113; called by muse, mutect2, varscan2
- PRAME | c.1013A>T p.D338V | Missense Mutation (SNP) | VAF 62/1075 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101287207; called by muse, mutect2
- PRCP | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 220/693 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV100476285; called by muse, mutect2, varscan2
- PRKAB2 | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 47/825 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99568040; called by muse, mutect2
- PROKR2 | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs758128077, COSV99450541; called by muse, mutect2
- PROM1 | c.1108A>T p.R370* | Nonsense Mutation (SNP) | VAF 135/742 reads (18%) | catalogued as COSV101477121; called by muse, mutect2, varscan2
- PRSS35 | c.788G>T p.W263L | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100864131; called by muse, mutect2, varscan2
- PSKH1 | c.883A>G p.M295V | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as rs1374332593, COSV99344935; called by muse, mutect2, varscan2
- PTCHD3 | c.1790C>G p.T597R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV101438953, COSV71257323; called by muse, mutect2, varscan2
- RABL3 | c.267T>A p.N89K | Missense Mutation (SNP) | VAF 67/434 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV99846620; called by muse, mutect2, varscan2
- RASSF2 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 44/313 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV101040888; called by muse, mutect2, varscan2
- RBFA | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100080284; called by muse, mutect2
- RBM25 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99998947; called by muse, mutect2, varscan2
- RC3H1 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV99281664; called by muse, mutect2, varscan2
- RFPL2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as COSV99964493; called by muse, mutect2, varscan2
- RFPL4B | c.183G>T p.L61F | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV101480721, COSV71437687; called by muse, mutect2, varscan2
- RIOK3 | c.958A>T p.N320Y | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259428; called by muse, mutect2, varscan2
- RIPK4 | c.131G>C p.W44S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100205277; called by muse, mutect2, varscan2
- RNASE11 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 279/1474 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV100250597, COSV60087657; called by muse, mutect2, varscan2
- ROBO1 | c.4675G>T p.D1559Y | Missense Mutation (SNP) | VAF 554/2876 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101459144; called by muse, mutect2, varscan2
- RPGRIP1 | c.739A>T p.K247* | Nonsense Mutation (SNP) | VAF 19/160 reads (12%) | catalogued as COSV99251598; called by muse, mutect2, varscan2
- RUNDC3B | c.673A>T p.I225F | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as COSV100407209; called by muse, mutect2, varscan2
- RUNDC3B | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.688); catalogued as COSV100407212; called by muse, mutect2, varscan2
- RYR1 | c.5011G>T p.A1671S | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.4); catalogued as COSV100616636, COSV62110536; called by muse, mutect2, varscan2
- RYR2 | c.5376A>G p.I1792M | Missense Mutation (SNP) | VAF 466/1554 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100772168; called by mutect2, varscan2
- RYR3 | c.3258G>T p.K1086N | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV101213759; called by muse, mutect2, varscan2
- SALL4 | c.1010A>C p.Q337P | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99409535, COSV99409779; called by muse, mutect2, varscan2
- SCARB2 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 52/625 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs773957659, COSV53667672; called by muse, mutect2
- SCN2A | c.1843C>A p.H615N | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99332981; called by muse, mutect2, varscan2
- SCN7A | c.1990T>A p.C664S | Missense Mutation (SNP) | VAF 99/655 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV69268054; called by muse, mutect2, varscan2
- SCN7A | c.1105G>T p.V369F | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.826); catalogued as rs1256613535; called by muse, mutect2
- SCN7A | c.1104G>T p.K368N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101313060; called by muse, mutect2
- SCNN1B | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV100225539, COSV100225883; called by muse, mutect2, varscan2
- SDSL | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 165/658 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV100615288; called by muse, mutect2, varscan2
- SEMA3D | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV99407196; called by muse, varscan2
- SEMA4F | c.1374G>T p.E458D | Missense Mutation (SNP) | VAF 204/659 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100336108; called by muse, mutect2, varscan2
- SERINC3 | c.570G>C p.W190C | Missense Mutation (SNP) | VAF 111/579 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99667935; called by muse, mutect2, varscan2
- SERPINA11 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 100/1140 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.665); catalogued as COSV100593918, COSV100594176; called by muse, mutect2
- SETD5 | c.4183G>C p.G1395R | Missense Mutation (SNP) | VAF 94/394 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV100200987, COSV100201001; called by muse, mutect2, varscan2
- SETX | c.5626A>T p.N1876Y | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV99810604; called by muse, mutect2, varscan2
- SGIP1 | c.1550C>A p.A517E | Missense Mutation (SNP) | VAF 48/545 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99392498; called by muse, mutect2
- SI | c.4087C>A p.P1363T | Missense Mutation (SNP) | VAF 34/507 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100016718, COSV52292312; called by muse, mutect2
- SIK3 | c.1330G>T p.E444* (on ENST00000445177 / NM_001366686.2; = p.E450* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 148/469 reads (32%) | catalogued as COSV99408614; called by muse, mutect2, varscan2
- SIPA1L3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756536229, COSV99730054; called by muse, mutect2, varscan2
- SLC12A2 | c.3074A>C p.D1025A | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99321435; called by muse, varscan2
- SLC17A6 | c.971G>T p.W324L | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99582094; called by muse, mutect2, varscan2
- SLC22A16 | c.1539G>A p.M513I | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100397827; called by muse, mutect2, varscan2
- SLC30A3 | c.616A>T p.S206C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99273816; called by muse, mutect2, varscan2
- SLC38A5 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV100476702; called by muse, mutect2, varscan2
- SLC6A17 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); catalogued as COSV100521468; called by muse, mutect2, varscan2
- SLC9C2 | c.2164-1G>T p.X722_splice | Splice Site (SNP) | VAF 14/156 reads (9%) | catalogued as rs779235280, COSV100876943; called by mutect2, varscan2
- SMYD1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 140/435 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1205453259, COSV101352493; called by muse, mutect2, varscan2
- SND1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 58/666 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100690917; called by muse, mutect2
- SPAG17 | c.4498A>G p.T1500A | Missense Mutation (SNP) | VAF 119/662 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1379404512, COSV100310118; called by muse, mutect2, varscan2
- SPAG17 | c.1246+1G>T p.X416_splice | Splice Site (SNP) | VAF 641/3323 reads (19%) | catalogued as COSV100310122; called by muse, mutect2, varscan2
- SPATA31D1 | c.3023C>A p.T1008N | Missense Mutation (SNP) | VAF 289/1081 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs767994748, COSV100782988; called by muse, mutect2, varscan2
- SPRED2 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 58/427 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.526); catalogued as COSV100710302; called by muse, mutect2, varscan2
- SPTA1 | c.3376G>T p.D1126Y | Missense Mutation (SNP) | VAF 97/407 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935382, COSV63750078; called by muse, mutect2, varscan2
- SPTBN1 | c.3794G>T p.S1265I | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1310128998, COSV100443219; called by muse, varscan2
- SPTLC3 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 35/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100983251; called by muse, mutect2
- SSPN | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 52/783 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1474582625, COSV54381939; called by muse, mutect2
- STC2 | c.698A>G p.K233R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99438588; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2811G>T p.L937F | Missense Mutation (SNP) | VAF 74/508 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV100561931; called by muse, mutect2, varscan2
- STRC | c.4067G>C p.C1356S | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101348021; called by muse, mutect2, varscan2
- STRIP2 | c.2389G>T p.V797L | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as COSV50803582, COSV99974070; called by muse, mutect2, varscan2
- SUCLA2 | c.955G>T p.D319Y (on ENST00000643023; = p.D298Y on NM_003850.3) | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101074922; called by muse, mutect2, varscan2
- SVIL | c.2567C>A p.T856K (on ENST00000355867 / NM_021738.3; = p.T430K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100881467; called by muse, mutect2
- SYCP1 | c.2853G>A p.M951I | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101051110; called by muse, mutect2, varscan2
- SYNE1 | c.15972C>A p.D5324E (on ENST00000367255 / NM_182961.4; = p.D5253E on NM_033071.3) | Missense Mutation (SNP) | VAF 32/387 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99574904; called by muse, mutect2
- SYNE1 | c.5101-2A>C p.X1701_splice (on ENST00000367255 / NM_182961.4; = p.X1708_splice on NM_033071.3) | Splice Site (SNP) | VAF 20/188 reads (11%) | catalogued as COSV99574909; called by mutect2, varscan2
- SYS1 | c.218A>T p.N73I | Missense Mutation (SNP) | VAF 78/578 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99713965; called by muse, mutect2, varscan2
- SYT14 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 45/201 reads (22%) | catalogued as COSV99655874; called by muse, mutect2, varscan2
- TACC2 | c.5601G>T p.Q1867H (on ENST00000334433; = p.Q58H on NM_206861.3) | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV100553407; called by muse, mutect2, varscan2
- TAF1L | c.4972C>A p.P1658T | Missense Mutation (SNP) | VAF 274/939 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.293); catalogued as COSV99644189; called by muse, mutect2, varscan2
- TAS2R14 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.233); catalogued as rs780814771, COSV101115355; called by muse, mutect2, varscan2
- TBX20 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101282405, COSV68783067; called by muse, mutect2, varscan2
- TBX5 | c.810C>A p.N270K | Missense Mutation (SNP) | VAF 86/964 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV100091871; called by muse, mutect2
- TENT4B | c.919G>T p.D307Y (on ENST00000561678 / NM_001365323.2; = p.D292Y on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100666141; called by muse, mutect2, varscan2
- TFCP2 | c.93G>C p.Q31H | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs748065303, COSV99227796; called by muse, mutect2, varscan2
- THSD7A | c.4384C>A p.Q1462K | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101448845; called by muse, mutect2, varscan2
- TINAG | c.968C>A p.A323E | Missense Mutation (SNP) | VAF 110/1153 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.383); catalogued as COSV99450491; called by muse, mutect2
- TINAGL1 | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 37/124 reads (30%) | catalogued as COSV54700139, COSV99593046; called by muse, mutect2, varscan2
- TLX1 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV100930095, COSV100930113; called by muse, mutect2, varscan2
- TMEM154 | c.364+1G>T p.X122_splice | Splice Site (SNP) | VAF 41/402 reads (10%) | catalogued as COSV100433188; called by muse, mutect2, varscan2
- TMEM200C | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763098598, COSV101274858, COSV67309485; called by muse, varscan2
- TMPRSS15 | c.1987G>T p.D663Y | Missense Mutation (SNP) | VAF 171/748 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99518900; called by muse, mutect2, varscan2
- TMSB4X | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV101020331, COSV101020361; called by muse, mutect2, varscan2
- TNN | c.1736G>T p.G579V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99512698; called by muse, varscan2
- TNN | c.3380G>T p.R1127M | Missense Mutation (SNP) | VAF 103/538 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53437472, COSV99512700; called by muse, mutect2, varscan2
- TNR | c.2597C>G p.P866R | Missense Mutation (SNP) | VAF 58/453 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV99690927; called by muse, mutect2, varscan2
- TRAF5 | c.790-1G>A p.X264_splice | Splice Site (SNP) | VAF 52/581 reads (9%) | catalogued as COSV99807557; called by muse, mutect2
- TRHDE | c.473T>A p.M158K | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV99671979; called by muse, mutect2, varscan2
- TRHDE | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV99671980; called by muse, mutect2, varscan2
- TRMT1L | c.1393G>C p.V465L | Missense Mutation (SNP) | VAF 87/609 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV100834711; called by muse, mutect2, varscan2
- TSPAN2 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101050046; called by muse, mutect2
- TTC29 | c.966G>T p.K322N | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs767173768, COSV100284355; called by muse, mutect2, varscan2
- TTF2 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 47/500 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV101037756; called by muse, mutect2
- TTK | c.2246A>T p.D749V | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100036527; called by muse, mutect2, varscan2
- TTLL2 | c.784G>C p.V262L | Missense Mutation (SNP) | VAF 71/606 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99514921; called by muse, mutect2, varscan2
- TTLL5 | c.2050C>T p.L684F | Missense Mutation (SNP) | VAF 170/1359 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1032611319, COSV100091257; called by muse, mutect2, varscan2
- TTN | c.87029C>T p.P29010L (on ENST00000591111; = p.P21586L on NM_003319.4) | Missense Mutation (SNP) | VAF 60/281 reads (21%) | PolyPhen benign (0.003); catalogued as COSV59906301; called by muse, mutect2, varscan2
- TTN | c.56753A>G p.Q18918R (on ENST00000591111; = p.Q11494R on NM_003319.4) | Missense Mutation (SNP) | VAF 31/174 reads (18%) | PolyPhen benign (0.415); catalogued as COSV100624724; called by muse, mutect2, varscan2
- TTN | c.23225C>T p.A7742V (on ENST00000591111; = p.A6815V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/385 reads (25%) | PolyPhen possibly damaging (0.592); catalogued as rs1301357470, COSV100624733; called by mutect2, varscan2
- TTN | c.9302A>G p.D3101G (on ENST00000591111; = p.D3055G on NM_003319.4) | Missense Mutation (SNP) | VAF 101/493 reads (20%) | PolyPhen benign (0.367); catalogued as COSV100624741; called by muse, mutect2, varscan2
- TXLNB | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100625128; called by muse, mutect2, varscan2
- UBE2F | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 43/516 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99800410; called by muse, mutect2
- UNC13C | c.6252T>A p.F2084L | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99521717; called by muse, mutect2, varscan2
- UNC5B | c.1295-2A>C p.X432_splice | Splice Site (SNP) | VAF 13/116 reads (11%) | catalogued as COSV100101168; called by muse, mutect2, varscan2
- UNC5C | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 118/363 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs766583475, COSV101497999; called by muse, mutect2, varscan2
- UNC5D | c.1743G>T p.M581I | Missense Mutation (SNP) | VAF 131/474 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV99777816; called by muse, mutect2, varscan2
- UNC79 | c.7787G>A p.G2596D (on ENST00000393151 / NM_001346218.2; = p.G2419D on NM_020818.5) | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.961); catalogued as COSV56407802, COSV99829415; called by muse, mutect2, varscan2
- USF3 | c.4585C>A p.Q1529K | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as COSV100324918, COSV100325661; called by muse, mutect2, varscan2
- USH2A | c.11128G>T p.G3710C | Missense Mutation (SNP) | VAF 96/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100240248; called by muse, varscan2
- USH2A | c.6893C>T p.P2298L | Missense Mutation (SNP) | VAF 82/349 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100240256; called by muse, mutect2, varscan2
- USP29 | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 83/426 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99518467; called by muse, mutect2, varscan2
- USP7 | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 104/551 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100784356; called by muse, mutect2, varscan2
- UTS2B | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 78/918 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV100484330; called by muse, mutect2
- VEPH1 | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 128/821 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100747897; called by muse, mutect2, varscan2
- VPS35L | c.1783A>T p.K595* | Nonsense Mutation (SNP) | VAF 34/164 reads (21%) | catalogued as COSV99221490; called by muse, mutect2, varscan2
- VPS53 | c.597G>T p.Q199H (on ENST00000571805 / NM_001366253.2; = p.Q170H on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV99346545; called by muse, varscan2
- VRTN | c.171A>T p.E57D | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99832419; called by muse, mutect2, varscan2
- VSX1 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 51/359 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100942197; called by muse, mutect2, varscan2
- WDR17 | c.1737G>C p.E579D | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV99708079; called by muse, mutect2, varscan2
- WDR17 | c.3220-1G>T p.X1074_splice | Splice Site (SNP) | VAF 18/167 reads (11%) | catalogued as COSV99708080; called by muse, mutect2, varscan2
- WDR19 | c.3161C>T p.A1054V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.274); catalogued as COSV104386712; called by muse, mutect2, varscan2
- WSCD2 | c.78C>G p.Y26* | Nonsense Mutation (SNP) | VAF 112/888 reads (13%) | catalogued as COSV99775071; called by muse, mutect2, varscan2
- XAGE3 | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV100655693; called by muse, mutect2, varscan2
- XAGE5 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV100657851; called by muse, mutect2
- XK | c.687T>A p.F229L | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV101064769; called by muse, mutect2, varscan2
- XPO4 | c.1798A>T p.R600* | Nonsense Mutation (SNP) | VAF 56/185 reads (30%) | catalogued as COSV99689046; called by muse, mutect2, varscan2
- ZBTB21 | c.2335G>T p.E779* | Nonsense Mutation (SNP) | VAF 172/727 reads (24%) | catalogued as COSV100177320, COSV60403814; called by muse, mutect2, varscan2
- ZBTB41 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 73/719 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100963379; called by muse, mutect2, varscan2
- ZC3H18 | c.2384C>T p.S795L | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs147815597; called by muse, varscan2
- ZFHX3 | c.1639A>T p.T547S | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV99214185; called by muse, mutect2
- ZFHX4 | c.4419C>A p.S1473R | Missense Mutation (SNP) | VAF 117/559 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs540974936, COSV50478898, COSV99266312; called by muse, mutect2, varscan2
- ZIC1 | c.1334G>A p.W445* | Nonsense Mutation (SNP) | VAF 20/157 reads (13%) | catalogued as COSV51555085, COSV99292262; called by muse, mutect2, varscan2
- ZNF107 | c.464C>G p.T155S | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV100788464; called by muse, mutect2, varscan2
- ZNF133 | c.1471G>A p.E491K (on ENST00000316358 / NM_001352454.2; = p.E490K on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1023162988, COSV100315538; called by muse, mutect2
- ZNF154 | c.540G>C p.W180C | Missense Mutation (SNP) | VAF 116/850 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as rs777280887, COSV101377538, COSV70744932; called by muse, mutect2
- ZNF211 | c.1345G>T p.G449W (on ENST00000347302 / NM_198855.4; = p.G462W on NM_006385.5) | Missense Mutation (SNP) | VAF 86/413 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1405457836, COSV99560425; called by muse, mutect2, varscan2
- ZNF23 | c.1351A>G p.N451D | Missense Mutation (SNP) | VAF 80/232 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs754893318, COSV100612238; called by muse, mutect2, varscan2
- ZNF250 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1225378328, COSV52968208, COSV52969065; called by muse, mutect2, varscan2
- ZNF292 | c.1760A>G p.H587R | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100370928; called by muse, mutect2
- ZNF37A | c.1417G>T p.G473W | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61074492; called by muse, mutect2, varscan2
- ZNF385D | c.833C>G p.S278W | Missense Mutation (SNP) | VAF 102/449 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99875930; called by muse, mutect2, varscan2
- ZNF408 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 123/440 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100305606; called by muse, mutect2, varscan2
- ZNF532 | c.1616A>T p.E539V | Missense Mutation (SNP) | VAF 29/491 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV60172438; called by muse, mutect2
- ZNF536 | c.1886A>T p.K629M | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100835650; called by muse, mutect2, varscan2
- ZNF606 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 444/2494 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.816); catalogued as COSV100357488; called by muse, varscan2
- ZNF611 | c.583A>G p.R195G | Missense Mutation (SNP) | VAF 113/490 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100160521; called by muse, mutect2, varscan2
- ZNF804A | c.925C>G p.P309A | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV100169559; called by muse, mutect2, varscan2
- ZNF827 | c.601A>T p.T201S | Missense Mutation (SNP) | VAF 68/399 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV101061636; called by muse, mutect2, varscan2
- ZNF98 | c.1637A>G p.Y546C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1421558244, COSV63335121, COSV63337942; called by muse, mutect2, varscan2
- ZNFX1 | c.3977T>A p.I1326N | Missense Mutation (SNP) | VAF 85/501 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100872542; called by muse, mutect2, varscan2
- ZZEF1 | c.6739G>A p.V2247M | Missense Mutation (SNP) | VAF 83/486 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779969346, COSV101067960; called by muse, mutect2, varscan2
- AC004593.2 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2
- ACAN | c.4496C>T p.S1499F | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANK2 | c.11737A>G p.T3913A | Missense Mutation (SNP) | VAF 46/717 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); called by muse, mutect2
- BAK1 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); called by muse, mutect2
- BLOC1S6 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- BRD7 | c.666del p.K223Sfs*7 | Frame Shift Del (DEL) | VAF 114/500 reads (23%) | called by mutect2, varscan2
- CACNA1A | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 18/502 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2
- CLEC4E | c.414del p.F138Lfs*21 | Frame Shift Del (DEL) | VAF 124/548 reads (23%) | called by mutect2, pindel, varscan2
- DGKZ | c.1052G>T p.R351M (on ENST00000454345 / NM_001105540.2; = p.R163M on NM_003646.4) | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- DPP8 | c.757C>G p.H253D (on ENST00000341861 / NM_001320875.2; = p.H237D on NM_017743.6) | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- GAS2L2 | c.1586C>A p.T529K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.298); called by mutect2, varscan2
- GNE | c.1556C>T p.S519L (on ENST00000396594 / NM_001128227.3; = p.S488L on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/1218 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- GREB1 | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- GRIK4 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HKDC1 | c.2291G>A p.G764D | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- HPSE2 | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 49/644 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); called by muse, mutect2
- IGKV1D-42 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 159/1004 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, varscan2
- ITGA8 | c.3126del p.R1043Dfs*7 | Frame Shift Del (DEL) | VAF 25/228 reads (11%) | called by pindel, varscan2
- ITIH6 | c.95G>T p.S32I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KRT85 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- LAMA2 | c.9297del p.K3099Nfs*13 | Frame Shift Del (DEL) | VAF 51/309 reads (17%) | called by mutect2, pindel, varscan2
- LETMD1 | c.661-1G>A p.X221_splice | Splice Site (SNP) | VAF 16/398 reads (4%) | called by muse, mutect2
- LRRN2 | c.1871C>A p.A624D | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MARCO | c.1064-2del p.X355_splice | Splice Site (DEL) | VAF 55/298 reads (18%) | called by mutect2, pindel, varscan2
- MFSD9 | c.774G>C p.R258S | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.056); called by muse, mutect2
- MGME1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 15/358 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2
- MINDY4 | c.1293del p.W431* | Frame Shift Del (DEL) | VAF 51/304 reads (17%) | called by mutect2, pindel, varscan2
- MLF1 | c.404del p.G135Efs*3 | Frame Shift Del (DEL) | VAF 48/316 reads (15%) | called by mutect2, pindel, varscan2
- MROH2B | c.539dup p.N180Kfs*5 | Frame Shift Ins (INS) | VAF 182/617 reads (29%) | called by mutect2, pindel, varscan2
- MYH8 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR6F1 | c.164dup p.L55Ffs*67 | Frame Shift Ins (INS) | VAF 128/797 reads (16%) | called by mutect2, pindel, varscan2
- PCLO | c.11008A>G p.K3670E | Missense Mutation (SNP) | VAF 113/1284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- PRAMEF10 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 74/2000 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- RREB1 | c.3218C>T p.S1073L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- RYR3 | c.4562G>T p.W1521L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2
- SECISBP2L | c.2466del p.A823Qfs*12 (on ENST00000559471 / NM_001193489.2; = p.A778Qfs*12 on NM_014701.4) | Frame Shift Del (DEL) | VAF 186/1431 reads (13%) | called by mutect2, pindel, varscan2
- SLC2A7 | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- SLX4 | c.2003G>A p.G668D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, varscan2
- SNRNP27 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 75/563 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- STAB2 | c.4958del p.G1653Vfs*2 | Frame Shift Del (DEL) | VAF 92/974 reads (9%) | called by mutect2, pindel
- TAAR9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2
- TMEM236 | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 131/596 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TRAV1-1 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 33/438 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- ZNF37A | c.321del p.K107Nfs*4 | Frame Shift Del (DEL) | VAF 98/1012 reads (10%) | called by mutect2, pindel, varscan2
- ZNF488 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY5 | c.870C>T p.R290= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101518453; called by muse, mutect2, varscan2
- AKAP9 | c.9219G>T p.L3073= (on ENST00000359028; = p.L3049= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 398/2000 reads (20%) | catalogued as COSV100662875; called by muse, mutect2, varscan2
- APAF1 | c.586C>T p.L196= (on ENST00000551964 / NM_181861.2; = p.L185= on NM_001160.3) | Silent (SNP) | VAF 89/225 reads (40%) | catalogued as COSV100244355; called by muse, mutect2, varscan2
- APOB | c.13428A>T p.I4476= | Silent (SNP) | VAF 70/293 reads (24%) | catalogued as COSV99267213; called by muse, mutect2, varscan2
- ASIC5 | c.369C>A p.A123= | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as COSV101539785; called by muse, mutect2, varscan2
- ASXL1 | c.1326G>C p.V442= | Silent (SNP) | VAF 28/271 reads (10%) | catalogued as COSV100037555, COSV100040722; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2106G>T p.L702= | Silent (SNP) | VAF 67/318 reads (21%) | catalogued as COSV100377113; called by muse, mutect2, varscan2
- BEND5 | c.858G>T p.A286= | Silent (SNP) | VAF 80/789 reads (10%) | catalogued as COSV100884166; called by muse, mutect2
- BMP10 | c.210C>T p.D70= | Silent (SNP) | VAF 72/737 reads (10%) | catalogued as COSV99770555; called by muse, mutect2
- C18orf25 | c.48C>T p.S16= | Silent (SNP) | VAF 87/874 reads (10%) | catalogued as rs374873414; called by muse, mutect2
- C3orf70 | c.378T>A p.I126= | Silent (SNP) | VAF 303/741 reads (41%) | catalogued as COSV100621322; called by muse, mutect2, varscan2
- CCDC102B | c.1144A>C p.R382= | Silent (SNP) | VAF 29/298 reads (10%) | catalogued as COSV100104415; called by muse, mutect2
- CDA | c.378C>G p.V126= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV100906377; called by muse, mutect2, varscan2
- CDH10 | c.1401C>A p.P467= | Silent (SNP) | VAF 54/302 reads (18%) | catalogued as COSV100052678; called by muse, mutect2, varscan2
- CDH16 | c.873C>T p.T291= | Silent (SNP) | VAF 12/354 reads (3%) | called by muse, mutect2
- CDH23 | c.8919G>A p.E2973= | Silent (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- CEMP1 | c.279G>T p.L93= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV53551166; called by muse, varscan2
- CEP290 | c.7023T>G p.L2341= | Silent (SNP) | VAF 166/401 reads (41%) | catalogued as COSV100469472; called by muse, mutect2, varscan2
- CFAP91 | c.2106G>T p.L702= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV99847401; called by muse, mutect2, varscan2
- CHIA | c.1362C>A p.V454= (on ENST00000343320; = p.V346= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/237 reads (19%) | catalogued as COSV100588803; called by muse, mutect2, varscan2
- CHML | c.78A>G p.A26= | Silent (SNP) | VAF 23/368 reads (6%) | catalogued as COSV100087692; called by muse, mutect2
- CHRM2 | c.672T>A p.P224= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV100281710; called by muse, mutect2
- CHSY3 | c.2169C>T p.F723= | Silent (SNP) | VAF 44/1012 reads (4%) | called by muse, mutect2
- CIDEA | c.282A>T p.G94= | Silent (SNP) | VAF 35/256 reads (14%) | catalogued as rs150815921, COSV100255303; called by muse, mutect2, varscan2
- CNTNAP1 | c.75C>T p.C25= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99226847; called by muse, mutect2, varscan2
- CNTNAP2 | c.411C>A p.P137= | Silent (SNP) | VAF 30/210 reads (14%) | catalogued as COSV62217057; called by muse, mutect2, varscan2
- CORIN | c.3027C>A p.V1009= | Silent (SNP) | VAF 22/403 reads (5%) | catalogued as COSV99904217; called by muse, mutect2
- CRABP1 | c.180C>G p.R60= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100211289; called by muse, mutect2
- CRACD | c.3531G>T p.T1177= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV99949836; called by muse, mutect2, varscan2
- CYP17A1 | c.1095C>T p.P365= | Silent (SNP) | VAF 57/280 reads (20%) | catalogued as rs759770054, COSV100882131; called by muse, mutect2, varscan2
- DOCK1 | c.4911G>A p.T1637= | Silent (SNP) | VAF 46/543 reads (8%) | catalogued as rs61733305; called by muse, mutect2
- EBAG9 | c.51A>G p.T17= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100520869; called by muse, mutect2, varscan2
- EMILIN2 | c.1128G>C p.L376= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as rs1321949084, COSV99598798, COSV99599003; called by muse, mutect2
- EML5 | c.927G>C p.V309= | Silent (SNP) | VAF 77/830 reads (9%) | catalogued as COSV100716079; called by muse, mutect2
- EPB41L3 | c.834G>C p.T278= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as COSV100549970; called by muse, mutect2, varscan2
- ERCC3 | c.993G>A p.G331= | Silent (SNP) | VAF 258/2017 reads (13%) | catalogued as rs148629399; called by muse, mutect2, varscan2
- FAM135B | c.339G>T p.V113= | Silent (SNP) | VAF 184/385 reads (48%) | catalogued as COSV99357895; called by muse, mutect2, varscan2
- FAM71B | c.318C>A p.A106= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV100262255; called by muse, mutect2, varscan2
- FASLG | c.399C>T p.H133= | Silent (SNP) | VAF 31/252 reads (12%) | catalogued as rs1049754208, COSV100390597; called by muse, mutect2, varscan2
- FAT4 | c.12099C>A p.A4033= | Silent (SNP) | VAF 18/175 reads (10%) | catalogued as rs774481338, COSV100629701, COSV58673897; called by muse, mutect2, varscan2
- FCAR | c.582C>T p.Y194= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs749038112, COSV62028254; called by muse, mutect2, varscan2
- FCRL3 | c.660A>T p.P220= | Silent (SNP) | VAF 98/420 reads (23%) | catalogued as COSV100943470; called by muse, mutect2, varscan2
- GAPVD1 | c.3588T>C p.C1196= (on ENST00000394104; = p.C1205= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/463 reads (23%) | catalogued as rs867478093, COSV52924737; called by muse, mutect2, varscan2
- GCSAML | c.225C>T p.I75= | Silent (SNP) | VAF 179/965 reads (19%) | catalogued as COSV63577526; called by muse, mutect2, varscan2
- GPR139 | c.342C>A p.T114= | Silent (SNP) | VAF 102/497 reads (21%) | catalogued as COSV100429972, COSV100429983; called by muse, mutect2, varscan2
- GPR4 | c.60G>T p.P20= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs760707691, COSV100547170; called by muse, mutect2, varscan2
- GPR6 | c.372C>A p.G124= | Silent (SNP) | VAF 28/302 reads (9%) | catalogued as COSV99254477; called by muse, mutect2
- GPR65 | c.444C>A p.V148= | Silent (SNP) | VAF 64/744 reads (9%) | catalogued as COSV99966133; called by muse, mutect2
- HHIPL2 | c.553C>T p.L185= | Silent (SNP) | VAF 64/317 reads (20%) | catalogued as rs753325195, COSV100597029; called by muse, mutect2, varscan2
- HOXC10 | c.90C>G p.G30= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100329144; called by muse, mutect2
- HRG | c.18A>G p.A6= | Silent (SNP) | VAF 21/200 reads (11%) | catalogued as COSV99214987; called by muse, mutect2, varscan2
- HTR1E | c.1029C>A p.L343= | Silent (SNP) | VAF 54/472 reads (11%) | catalogued as COSV100541235; called by muse, mutect2, varscan2
- HTR4 | c.66G>A p.L22= | Silent (SNP) | VAF 144/892 reads (16%) | catalogued as rs201439456, COSV58796745; called by muse, mutect2, varscan2
- ICE1 | c.5769A>C p.A1923= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV99665411; called by muse, mutect2, varscan2
- IFIT1 | c.537T>A p.A179= | Silent (SNP) | VAF 59/615 reads (10%) | catalogued as COSV100878760; called by muse, mutect2
- IGHV1-18 | c.102G>T p.G34= | Silent (SNP) | VAF 71/632 reads (11%) | catalogued as rs781952536; called by muse, mutect2, varscan2
- IGSF22 | c.2623C>A p.R875= (on ENST00000319338; = p.R976= on NM_173588.4) | Silent (SNP) | VAF 118/354 reads (33%) | catalogued as COSV55011821, COSV99773831; called by muse, mutect2, varscan2
- INHBC | c.336T>A p.T112= | Silent (SNP) | VAF 246/2011 reads (12%) | catalogued as COSV100548039; called by muse, mutect2, varscan2
- JPH2 | c.48G>C p.G16= | Silent (SNP) | VAF 15/158 reads (9%) | catalogued as rs917953744, COSV100652615; called by muse, mutect2, varscan2
- KCNK9 | c.705C>T p.I235= | Silent (SNP) | VAF 23/215 reads (11%) | catalogued as rs747620541, COSV57281660; called by muse, mutect2, varscan2
- KLK6 | c.492C>A p.S164= | Silent (SNP) | VAF 94/551 reads (17%) | catalogued as COSV100037810; called by muse, mutect2, varscan2
- KMO | c.681T>A p.P227= | Silent (SNP) | VAF 30/319 reads (9%) | catalogued as COSV100844713; called by muse, mutect2
- LDLRAD2 | c.702G>A p.L234= | Silent (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- LOXL1 | c.1383C>T p.Y461= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs748019800, COSV56094560; called by muse, varscan2
- LRGUK | c.150G>A p.T50= | Silent (SNP) | VAF 126/385 reads (33%) | catalogued as rs1323093580, COSV99603715, COSV99604561; called by muse, mutect2, varscan2
- LRP2 | c.7347C>A p.A2449= | Silent (SNP) | VAF 28/259 reads (11%) | catalogued as COSV99789798; called by muse, mutect2, varscan2
- MAGED2 | c.1179G>A p.E393= | Silent (SNP) | VAF 52/608 reads (9%) | catalogued as COSV99514712; called by muse, mutect2
- MGAM | c.1950C>T p.G650= | Silent (SNP) | VAF 48/413 reads (12%) | catalogued as COSV101527693; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1425C>T p.S475= | Silent (SNP) | VAF 20/548 reads (4%) | called by muse, mutect2
- MUC16 | c.26715G>C p.V8905= | Silent (SNP) | VAF 212/808 reads (26%) | catalogued as COSV101200848; called by muse, mutect2, varscan2
- MUC16 | c.10584G>T p.L3528= | Silent (SNP) | VAF 698/2515 reads (28%) | catalogued as COSV101200851; called by muse, mutect2, varscan2
- MYCBP2 | c.10182A>T p.I3394= (on ENST00000357337; = p.I3432= on NM_015057.5) | Silent (SNP) | VAF 105/415 reads (25%) | catalogued as COSV100631378; called by muse, mutect2, varscan2
- MYT1L | c.1707C>T p.L569= | Silent (SNP) | VAF 82/258 reads (32%) | catalogued as COSV101221216; called by muse, mutect2, varscan2
- NEDD4L | c.1494C>T p.F498= (on ENST00000400345 / NM_001144967.3; = p.F478= on NM_015277.6) | Silent (SNP) | VAF 38/386 reads (10%) | catalogued as COSV99896174; called by muse, mutect2
- NEO1 | c.3102A>T p.A1034= | Silent (SNP) | VAF 31/384 reads (8%) | catalogued as COSV99982604; called by muse, mutect2
- NFYC | c.573G>A p.V191= | Silent (SNP) | VAF 39/902 reads (4%) | called by muse, mutect2
- NID1 | c.987C>T p.P329= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as COSV51621162, COSV99938075; called by muse, mutect2, varscan2
- NOTCH3 | c.5091G>T p.V1697= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV99658438; called by muse, varscan2
- NPY4R | c.186G>A p.L62= | Silent (SNP) | VAF 76/712 reads (11%) | catalogued as COSV100966201; called by muse, mutect2, varscan2
- ONECUT1 | c.1071G>T p.P357= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100009383; called by muse, mutect2, varscan2
- OPALIN | c.351C>T p.D117= | Silent (SNP) | VAF 116/1118 reads (10%) | catalogued as COSV100959650; called by muse, mutect2, varscan2
- OR10G4 | c.247T>C p.L83= | Silent (SNP) | VAF 191/866 reads (22%) | catalogued as COSV100304935; called by muse, varscan2
- OR14C36 | c.894C>A p.A298= | Silent (SNP) | VAF 96/425 reads (23%) | catalogued as COSV100507615, COSV58601159; called by muse, mutect2, varscan2
- OR2AK2 | c.249C>A p.V83= | Silent (SNP) | VAF 240/971 reads (25%) | catalogued as COSV100824252; called by muse, mutect2, varscan2
- OR3A3 | c.492C>T p.N164= | Silent (SNP) | VAF 208/1086 reads (19%) | catalogued as rs1354761038, COSV99351494; called by muse, mutect2, varscan2
- OR52K1 | c.627G>A p.V209= | Silent (SNP) | VAF 593/2106 reads (28%) | catalogued as rs1387157755, COSV100297711, COSV56905080; called by muse, mutect2, varscan2
- OTOP1 | c.1197G>T p.S399= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as COSV99587969; called by muse, mutect2, varscan2
- PAM | c.2199A>C p.A733= | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as COSV99173718; called by muse, mutect2, varscan2
- PARP16 | c.501G>C p.L167= | Silent (SNP) | VAF 27/181 reads (15%) | catalogued as COSV99975622; called by muse, mutect2, varscan2
- PCDH7 | c.2358A>G p.G786= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100688565; called by muse, mutect2, varscan2
- PCDHA10 | c.324C>T p.I108= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV56554934; called by muse, mutect2, varscan2
- PDE1C | c.810C>T p.Y270= | Silent (SNP) | VAF 72/700 reads (10%) | catalogued as rs375192379, COSV100370815; called by muse, mutect2, varscan2
- PIGR | c.999G>T p.L333= | Silent (SNP) | VAF 18/234 reads (8%) | catalogued as COSV100732592; called by muse, mutect2
- PLA2G2F | c.174G>A p.L58= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV100907925; called by muse, mutect2, varscan2
- PLXNA2 | c.1911G>A p.L637= | Silent (SNP) | VAF 212/855 reads (25%) | catalogued as COSV100885668, COSV65443099; called by muse, mutect2, varscan2
- POLK | c.1758A>G p.E586= | Silent (SNP) | VAF 46/206 reads (22%) | catalogued as COSV54033660; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.792G>T p.R264= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99461683; called by muse, mutect2, varscan2
- PPY | c.135G>A p.Q45= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as COSV56823438, COSV56823890; called by muse, mutect2, varscan2
- PRDM1 | c.2202C>T p.D734= | Silent (SNP) | VAF 60/658 reads (9%) | catalogued as COSV100958946; called by muse, mutect2
- PRLR | c.1449T>C p.H483= | Silent (SNP) | VAF 110/604 reads (18%) | catalogued as COSV99184688; called by muse, mutect2, varscan2
- PROM2 | c.2025C>T p.P675= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100469303; called by muse, mutect2, varscan2
- PXDN | c.2124G>T p.L708= | Silent (SNP) | VAF 20/209 reads (10%) | catalogued as COSV99414542; called by muse, mutect2
- RANBP3L | c.168C>T p.T56= | Silent (SNP) | VAF 116/903 reads (13%) | catalogued as COSV99683995; called by muse, mutect2, varscan2
- RASAL1 | c.1551C>G p.G517= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99922026; called by muse, mutect2, varscan2
- RGS7 | c.975G>A p.Q325= | Silent (SNP) | VAF 42/219 reads (19%) | catalogued as COSV58535504; called by muse, varscan2
- RORB | c.852G>T p.V284= (on ENST00000396204 / NM_001365023.1; = p.V273= on NM_006914.4) | Silent (SNP) | VAF 173/547 reads (32%) | catalogued as COSV100974441, COSV65339336; called by muse, mutect2, varscan2
- ROS1 | c.4818T>A p.T1606= | Silent (SNP) | VAF 50/505 reads (10%) | catalogued as COSV100877565; called by muse, mutect2, varscan2
- RXRG | c.282C>A p.A94= | Silent (SNP) | VAF 59/272 reads (22%) | catalogued as COSV100717759; called by muse, mutect2, varscan2
- SCN3A | c.1929G>A p.K643= | Silent (SNP) | VAF 23/590 reads (4%) | called by muse, mutect2
- SLC30A8 | c.93G>A p.P31= | Silent (SNP) | VAF 69/360 reads (19%) | catalogued as rs751667454, COSV69968152, COSV69973921; called by muse, mutect2, varscan2
- SLC7A14 | c.363C>G p.T121= | Silent (SNP) | VAF 54/303 reads (18%) | catalogued as COSV99200818; called by muse, mutect2, varscan2
- SLCO5A1 | c.372C>G p.L124= | Silent (SNP) | VAF 24/221 reads (11%) | catalogued as COSV99480724; called by muse, mutect2
- SLIT1 | c.2571C>G p.S857= | Silent (SNP) | VAF 44/279 reads (16%) | catalogued as COSV99822226; called by muse, mutect2, varscan2
- SORBS2 | c.1362G>A p.K454= | Silent (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2, varscan2
- SSX3 | c.429A>G p.G143= | Silent (SNP) | VAF 123/904 reads (14%) | catalogued as COSV100035436; called by mutect2, varscan2
- SV2B | c.864C>G p.T288= | Silent (SNP) | VAF 180/571 reads (32%) | catalogued as COSV100370865, COSV57701658; called by muse, mutect2, varscan2
- SYNE3 | c.99G>T p.T33= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs146245189, COSV100516384; called by muse, mutect2, varscan2
- TBC1D2 | c.2020C>T p.L674= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs1421288192, COSV100580107; called by muse, mutect2, varscan2
- TBC1D3I | c.321G>A p.R107= | Silent (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- TBX4 | c.948G>A p.P316= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs765251401, COSV53610352; called by muse, mutect2, varscan2
- THOC1 | c.1047A>G p.Q349= | Silent (SNP) | VAF 77/432 reads (18%) | catalogued as rs1249681716, COSV99863558; called by muse, mutect2, varscan2
- TMEM44 | c.957G>A p.K319= (on ENST00000392432 / NM_001166305.2; = p.K272= on NM_138399.5) | Silent (SNP) | VAF 109/901 reads (12%) | catalogued as rs771233810, COSV99861949; called by muse, mutect2, varscan2
- TMEM8B | c.186C>T p.A62= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV100941698; called by muse, mutect2, varscan2
- TNN | c.1737G>T p.G579= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV99512699; called by muse, varscan2
- TRAV22 | c.15G>A p.L5= | Silent (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- TRAV8-7 | c.15C>A p.V5= | Silent (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2
- TRIM60 | c.366C>T p.S122= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV100594088; called by muse, mutect2, varscan2
- TRPA1 | c.2592G>A p.E864= | Silent (SNP) | VAF 40/173 reads (23%) | catalogued as rs769931136, COSV100084901, COSV51567133; called by muse, mutect2, varscan2
- TTI1 | c.2973C>A p.G991= | Silent (SNP) | VAF 85/614 reads (14%) | catalogued as COSV100989718, COSV100989825; called by mutect2, varscan2
- TTN | c.15000G>A p.Q5000= (on ENST00000591111; = p.Q4073= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/195 reads (29%) | catalogued as rs1376351122, COSV100624735; called by muse, mutect2, varscan2
- TXLNB | c.531T>C p.R177= | Silent (SNP) | VAF 22/188 reads (12%) | catalogued as COSV100625127; called by muse, mutect2, varscan2
- UBE3C | c.774A>G p.Q258= | Silent (SNP) | VAF 47/180 reads (26%) | catalogued as rs779273961, COSV100780044; called by muse, mutect2, varscan2
- VIRMA | c.783G>A p.E261= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV99889090; called by muse, mutect2, varscan2
- VSTM2A | c.345C>T p.S115= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV56496034; called by mutect2, varscan2
- WDR7 | c.51G>T p.A17= | Silent (SNP) | VAF 68/416 reads (16%) | catalogued as rs749728680, COSV99590151; called by muse, mutect2, varscan2
- ZNF239 | c.924C>A p.I308= | Silent (SNP) | VAF 39/348 reads (11%) | catalogued as rs754438172, COSV100021871; called by muse, mutect2, varscan2
- ZNF774 | c.654C>T p.D218= | Silent (SNP) | VAF 26/219 reads (12%) | catalogued as COSV100586442; called by muse, mutect2, varscan2
- ZNF804A | c.1599C>A p.S533= | Silent (SNP) | VAF 22/193 reads (11%) | catalogued as COSV100169562, COSV56450521; called by muse, mutect2, varscan2
- ATE1 | c.942+1014G>T | Intron (SNP) | VAF 75/494 reads (15%) | catalogued as COSV99817553; called by muse, mutect2, varscan2
- BET1L | c.169-25G>A | Intron (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1567A>T | RNA (SNP) | VAF 49/218 reads (22%) | called by muse, mutect2, varscan2
- C14orf177 | n.563G>T | RNA (SNP) | VAF 31/292 reads (11%) | catalogued as COSV100362729; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33869C>A | Intron (SNP) | VAF 97/562 reads (17%) | catalogued as COSV100280814, COSV100281709; called by muse, mutect2, varscan2
- COG5 | c.-13G>T | 5'UTR (SNP) | VAF 10/36 reads (28%) | catalogued as rs915925086, COSV99709264; called by muse, mutect2
- CTSL3P | n.190G>T | RNA (SNP) | VAF 81/349 reads (23%) | called by muse, mutect2, varscan2
- CTSL3P | n.191G>T | RNA (SNP) | VAF 81/346 reads (23%) | called by muse, mutect2, varscan2
- DCHS2 | n.1470C>A | RNA (SNP) | VAF 35/291 reads (12%) | catalogued as COSV100252783; called by muse, mutect2, varscan2
- KLC4 | c.-26+551C>T | Intron (SNP) | VAF 25/298 reads (8%) | catalogued as COSV99432436; called by muse, mutect2
- MASP1 | c.1303+5686C>A | Intron (SNP) | VAF 22/149 reads (15%) | catalogued as rs745444812, COSV56221819, COSV99962704; called by muse, mutect2, varscan2
- MIR1253 | n.90C>T | RNA (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2
- RBPMS2 | c.88-10751G>T | Intron (SNP) | VAF 32/140 reads (23%) | catalogued as rs1297255275, COSV100264951; called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+463A>T | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as COSV101530535; called by muse, mutect2, varscan2
- TTN | c.10361-3705T>C | Intron (SNP) | VAF 80/490 reads (16%) | catalogued as COSV100624738; called by muse, mutect2, varscan2
- UGGT2 | c.1031+1028A>T | Intron (SNP) | VAF 15/95 reads (16%) | catalogued as COSV100942632; called by muse, mutect2, varscan2
- XIST | n.9232C>T | RNA (SNP) | VAF 5/37 reads (14%) | called by mutect2, varscan2
